Somatic mutation profile of tumor specimen BA2238D (aliquot aq-BA2238D) from BEATAML1.0 case 2470, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 33.4 years (12,195 days).
Specimen BA2238D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8900ef7e-496e-4ab9-b322-af2cb7cd55e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2056D (Solid Tissue Normal), aliquot aq-BA2056D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7fd4d0c7-2c95-478f-835c-4af4b6165090

The open-access MAF lists 13 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 4, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.515G>A p.R172K | Missense Mutation (SNP) | VAF 117/247 reads (47%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs121913503, COSV57468734, COSV57468971, COSV57472976; ClinVar: pathogenic / not provided / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 109/116 reads (94%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAMTS12 | c.519C>A p.D173E | Missense Mutation (SNP) | VAF 54/106 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as rs780776532; called by muse, mutect2, varscan2
- CD207 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 76/147 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.176); catalogued as rs376010760; called by muse, mutect2, varscan2
- CNTNAP2 | c.1150C>A p.L384M | Missense Mutation (SNP) | VAF 79/134 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as COSV100667600, COSV62157168; called by muse, mutect2, varscan2
- DYSF | c.5860G>A p.E1954K | Missense Mutation (SNP) | VAF 154/287 reads (54%) | SIFT tolerated (0.84); PolyPhen benign (0.248); catalogued as rs1356633122, COSV99247888; called by muse, mutect2, varscan2
- OR4Q3 | c.484T>A p.F162I | Missense Mutation (SNP) | VAF 38/171 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- CRYGB | c.282C>T p.Y94= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs761095253, COSV53680117; called by muse, mutect2, varscan2
- HMCN1 | c.7824C>G p.T2608= | Silent (SNP) | VAF 20/423 reads (5%) | called by muse, mutect2
- RNF187 | c.627G>A p.E209= | Silent (SNP) | VAF 71/134 reads (53%) | called by muse, mutect2, varscan2
- ZNF335 | c.273G>T p.V91= | Silent (SNP) | VAF 5/97 reads (5%) | called by muse, mutect2
- DZANK1 | chr20:18381365 C>A | 3'Flank (SNP) | VAF 3/25 reads (12%) | called by muse, mutect2
- SSPOP | n.15303C>A | RNA (SNP) | VAF 5/104 reads (5%) | catalogued as COSV100947402; called by muse, mutect2
